Somatic mutation profile of tumor specimen TCGA-E7-A6MF-01A (aliquot TCGA-E7-A6MF-01A-12D-A32B-08) from TCGA case TCGA-E7-A6MF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 38.0 years (13,867 days).
Specimen TCGA-E7-A6MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ebd6437-ccae-4941-9a2d-4398d0aace42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A6MF-10B (Blood Derived Normal), aliquot TCGA-E7-A6MF-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fae2a514-1b84-41dd-9dbe-23d93c3abbc0

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Nonsense Mutation 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNM2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as rs1064793101, COSV58965790; ClinVar: likely pathogenic; called by muse, mutect2
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 32/81 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP9 | c.6422G>A p.R2141K (on ENST00000359028; = p.R2109K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs1357112566, COSV62350962; called by muse, mutect2, varscan2
- ALOXE3 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.401); catalogued as COSV59076544; called by muse, mutect2, varscan2
- BBX | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 62/263 reads (24%) | catalogued as COSV100362397; called by muse, mutect2, varscan2
- CAMK1D | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV66614837; called by muse, mutect2, varscan2
- CEBPZ | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV50018046; called by muse, mutect2, varscan2
- CIP2A | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV55419740; called by muse, mutect2, varscan2
- DERA | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV70774823; called by muse, mutect2, varscan2
- DLG1 | c.2198C>T p.S733L (on ENST00000419354 / NM_001290983.1; = p.S755L on NM_004087.2) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV58379178, COSV58381779; called by muse, mutect2, varscan2
- DLG1 | c.2086C>G p.Q696E (on ENST00000419354 / NM_001290983.1; = p.Q718E on NM_004087.2) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.179); catalogued as COSV58386151; called by muse, mutect2, varscan2
- DMXL1 | c.8329C>T p.Q2777* | Nonsense Mutation (SNP) | VAF 45/83 reads (54%) | catalogued as COSV100224014, COSV100225269; called by muse, mutect2, varscan2
- EEPD1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1019797143, COSV54200554; called by muse, mutect2, varscan2
- GLTP | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV59173176; called by muse, mutect2, varscan2
- GPR1 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.192); catalogued as COSV101329854, COSV67977106; called by muse, mutect2, varscan2
- H2AC6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as COSV100020137; called by muse, mutect2, varscan2
- HASPIN | c.2016G>C p.K672N | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV53996411; called by muse, mutect2, varscan2
- ISL2 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV51958412; called by muse, mutect2, varscan2
- MAGEC3 | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 60/62 reads (97%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV53579585, COSV68923893; called by muse, mutect2, varscan2
- MECOM | c.595C>T p.Q199* (on ENST00000468789 / NM_001105078.4; = p.Q387* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 61/112 reads (54%) | catalogued as COSV52959701; called by muse, mutect2, varscan2
- MECP2 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 55/57 reads (96%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1557136401, COSV57655185; called by muse, mutect2, varscan2
- MYO9A | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61853593; called by muse, mutect2, varscan2
- NOP2 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs763386179, COSV58904828, COSV58908135; called by muse, mutect2, varscan2
- PAK2 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV59082757; called by muse, mutect2, varscan2
- PIH1D1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as COSV99221268; called by muse, mutect2, varscan2
- PLS1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV61834540; called by muse, mutect2, varscan2
- PSMA2 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55031476; called by muse, mutect2, varscan2
- SMC1A | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 86/86 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV59130169; called by muse, varscan2
- SMC1A | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV59130181; called by muse, varscan2
- SMC1A | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV59130201; called by muse, mutect2, varscan2
- STRIP1 | c.1287-1G>C p.X429_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | catalogued as COSV63929925; called by muse, mutect2, varscan2
- TIMELESS | c.2572C>T p.R858* | Nonsense Mutation (SNP) | VAF 43/97 reads (44%) | catalogued as rs778017589, COSV57512769; called by muse, mutect2, varscan2
- TXLNB | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV64444674, COSV64444788; called by muse, mutect2, varscan2
- USP40 | c.1277A>C p.Q426P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99297401; called by muse, mutect2
- WDR62 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54336744; called by muse, mutect2, varscan2
- ABI2 | c.237G>A p.Q79= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV53693905; called by muse, mutect2, varscan2
- ACO1 | c.1758G>A p.L586= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV100008133, COSV59381511; called by muse, mutect2, varscan2
- CORO2A | c.903C>T p.S301= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs770220176, COSV59662779; called by muse, mutect2, varscan2
- KCNB2 | c.849G>A p.L283= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV73051060; called by muse, mutect2, varscan2
- NUP210L | c.447G>C p.L149= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV55151389; called by muse, mutect2, varscan2
- PPP1R16B | c.276C>T p.V92= | Silent (SNP) | VAF 75/175 reads (43%) | catalogued as COSV55379861; called by muse, mutect2, varscan2
- SAE1 | c.639C>T p.F213= | Silent (SNP) | VAF 73/132 reads (55%) | catalogued as COSV54296641; called by muse, mutect2, varscan2
- TMEM202 | c.510C>T p.L170= | Silent (SNP) | VAF 45/86 reads (52%) | catalogued as COSV58983029; called by muse, mutect2, varscan2
- ZBTB38 | c.273C>A p.I91= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV58542954; called by muse, mutect2, varscan2
- ZBTB38 | c.2820G>A p.R940= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV58542967; called by muse, mutect2, varscan2
- ZBTB38 | c.3342G>A p.Q1114= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as COSV58542983; called by muse, mutect2, varscan2
